Somatic mutation profile of tumor specimen TCGA-IN-A6RS-01A (aliquot TCGA-IN-A6RS-01A-12D-A34U-08) from TCGA case TCGA-IN-A6RS, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 76.1 years (27,808 days).
Specimen TCGA-IN-A6RS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2d32016-9249-4c77-91bd-83e491c2d262.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IN-A6RS-10A (Blood Derived Normal), aliquot TCGA-IN-A6RS-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee696b57-f6c1-4f4f-8903-98cafea03f1a

The open-access MAF lists 113 somatic variants for this specimen: 72 protein-altering or splice-affecting, 38 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 38, Nonsense Mutation 4, Intron 2, Translation Start Site 1, In Frame Del 1, Splice Site 1, Frame Shift Ins 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 9/29 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587781288, CM993216, COSV52664953, COSV52926626, COSV53155598; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM2A | c.1427C>A p.S476* (on ENST00000219054; = p.S397* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 27/94 reads (29%) | catalogued as COSV54585974, COSV99524758; called by muse, mutect2, varscan2
- ADGRE2 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.013); catalogued as rs754889485, COSV59693104; called by muse, mutect2, varscan2
- AK5 | c.1234C>T p.R412C (on ENST00000354567 / NM_174858.3; = p.R386C on NM_012093.4) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs551663062, COSV100642305; called by muse, mutect2, varscan2
- ANGPTL7 | c.436A>C p.K146Q | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.228); catalogued as rs1465678002, COSV100815607; called by muse, mutect2, varscan2
- AR | c.1769G>A p.G590E | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as HM971970, COSV65957180; called by muse, mutect2, varscan2
- B3GNT6 | c.82C>G p.Q28E | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV100845751; called by muse, varscan2
- BCHE | c.1226G>A p.R409K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100011916, COSV52259148; called by muse, mutect2, varscan2
- C10orf90 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760735148, COSV52950749; called by muse, mutect2, varscan2
- C11orf49 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99561461; called by mutect2, varscan2
- CAPN10 | c.1079G>C p.G360A | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV99549832; called by muse, mutect2, varscan2
- CCDC112 | c.278+1G>A p.X93_splice | Splice Site (SNP) | VAF 17/78 reads (22%) | catalogued as COSV101100321; called by muse, mutect2
- CDH19 | c.8G>T p.C3F | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100050622; called by muse, mutect2
- COL10A1 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV99684006; called by muse, mutect2, varscan2
- COL4A5 | c.3692C>T p.P1231L | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CD961924, COSV100086133, COSV100087461; called by muse, mutect2, varscan2
- CSMD3 | c.2197C>G p.L733V (on ENST00000297405 / NM_001363185.1; = p.L629V on NM_052900.3) | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99821016; called by muse, mutect2, varscan2
- DCLK1 | c.923C>G p.P308R | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV55190021, COSV99708495; called by muse, mutect2, varscan2
- DISP3 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1295611477, COSV53831846, COSV53834337; called by muse, mutect2, varscan2
- DLD | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 96/228 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs527263746, COSV99226708; called by muse, mutect2, varscan2
- DNAH5 | c.12994G>A p.V4332M | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.227); catalogued as rs779253735, COSV54245257; called by muse, mutect2, varscan2
- DUS1L | c.463G>C p.D155H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV100152327; called by muse, mutect2, varscan2
- FNBP4 | c.1856C>T p.S619L | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs768346504, COSV55451906, COSV99771337, COSV99771900; called by muse, mutect2, varscan2
- GFRA2 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV60778394; called by muse, mutect2, varscan2
- GLI3 | c.3899C>T p.A1300V | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as rs751790458, COSV67888541; called by muse, mutect2, varscan2
- GPR182 | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as rs768431217, COSV100267613, COSV55627526; called by muse, mutect2, varscan2
- GRM8 | c.2156C>T p.P719L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100279561, COSV58859601; called by muse, mutect2
- GTPBP2 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs1327855394, COSV61076287; called by muse, mutect2, varscan2
- IFI16 | c.1957G>T p.V653L (on ENST00000295809 / NM_001364867.2; = p.V597L on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as COSV99856828; called by muse, mutect2, varscan2
- IGF1R | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs138973619; called by muse, mutect2, varscan2
- IRF1 | c.346A>G p.T116A | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as COSV99810346; called by muse, mutect2, varscan2
- KCND2 | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 86/195 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58598129; called by muse, mutect2, varscan2
- KIAA0100 | c.3308C>T p.P1103L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756551263, COSV101197186; called by mutect2, varscan2
- KIAA1217 | c.1547G>A p.G516D | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100285992; called by muse, mutect2, varscan2
- KIF4B | c.2838G>T p.K946N | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as COSV101469146; called by muse, mutect2, varscan2
- LRIT1 | c.1418G>A p.R473Q | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.75); catalogued as rs762407963, COSV100927977; called by muse, mutect2, varscan2
- MYH14 | c.4231C>T p.R1411W | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs777626365, COSV99221423; called by muse, mutect2, varscan2
- N4BP2L2 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.345); catalogued as COSV99912365; called by muse, mutect2, varscan2
- NBAS | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as rs376113678; called by muse, mutect2, varscan2
- NBEAL2 | c.4481G>A p.R1494H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs980067639, COSV99434007; called by muse, mutect2
- NOTCH2 | c.4724C>T p.T1575I | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99862348; called by muse, mutect2, varscan2
- NPHP1 | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 14/70 reads (20%) | catalogued as COSV100337743; called by muse, mutect2, varscan2
- OR10S1 | c.351C>A p.C117* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as COSV101602437; called by muse, mutect2, varscan2
- OR2M2 | c.815A>T p.K272M | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as rs147832484, COSV100677137; called by muse, varscan2
- OR5H14 | c.917A>C p.K306T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV101454043; called by muse, mutect2, varscan2
- OR9Q1 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs925997482, COSV100109117; called by muse, mutect2, varscan2
- OXCT2 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV59594230; called by muse, mutect2, varscan2
- PASK | c.2713C>T p.R905W | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs146183956; called by muse, mutect2, varscan2
- PCDHGC4 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.938); catalogued as COSV52757547; called by muse, mutect2, varscan2
- RTN3 | c.2682G>T p.R894S (on ENST00000377819 / NM_001265589.2; = p.R98S on NM_006054.4) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100379771; called by muse, mutect2, varscan2
- SHC3 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV65438574; called by muse, mutect2, varscan2
- SIGLEC11 | c.1874C>A p.P625Q | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.106); catalogued as COSV101357042; called by muse, varscan2
- SMARCA1 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs1363265931, COSV100946281; called by muse, mutect2, varscan2
- SNX21 | c.455C>G p.T152S | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV99467159; called by muse, mutect2
- SPANXB1 | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs1375388891; called by muse, mutect2, varscan2
- SRRM2 | c.3400G>A p.E1134K | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV100069927; called by muse, mutect2, varscan2
- ST3GAL2 | c.293C>T p.T98I | Missense Mutation (SNP) | VAF 19/47 reads (40%) | PolyPhen possibly damaging (0.639); catalogued as COSV100735588; called by muse, mutect2, varscan2
- SULT1A2 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs776949288, COSV100186949; called by muse, mutect2, varscan2
- SYDE1 | c.1999C>T p.R667W | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1371727331, COSV54617791; called by muse, mutect2, varscan2
- SYNE1 | c.9868A>C p.K3290Q (on ENST00000367255 / NM_182961.4; = p.K3297Q on NM_033071.3) | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.232); catalogued as COSV99549854; called by muse, mutect2, varscan2
- TBX22 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1423081813, COSV64786617; called by muse, mutect2, varscan2
- TPO | c.1450G>A p.V484M | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100219383; called by muse, mutect2, varscan2
- TRPA1 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1252308881, COSV100082797, COSV51570876; called by muse, mutect2, varscan2
- TTN | c.4990C>T p.R1664W (on ENST00000591111; = p.R1618W on NM_003319.4) | Missense Mutation (SNP) | VAF 18/116 reads (16%) | PolyPhen probably damaging (0.932); catalogued as rs147695336, COSV60036391; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VAT1L | c.961C>A p.L321M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs528576825, COSV100212784; called by muse, mutect2, varscan2
- WAC | c.1474C>G p.Q492E | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV100610826; called by muse, mutect2, varscan2
- ZNF445 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV101253645; called by muse, mutect2, varscan2
- ZNF521 | c.2284C>T p.R762C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774902024, COSV100831287; called by muse, mutect2, varscan2
- ZNF605 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as rs974962247; called by muse, mutect2, varscan2
- ZNF625 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.089); catalogued as rs532558913, COSV61998753, COSV61999272; called by muse, mutect2, varscan2
- HERC6 | c.2653_2655del p.K885del | In Frame Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- KMT2C | c.8633_8634dup p.E2879Lfs*28 | Frame Shift Ins (INS) | VAF 33/89 reads (37%) | called by mutect2, pindel, varscan2
- TRIM32 | c.1482del p.W494Cfs*40 | Frame Shift Del (DEL) | VAF 9/60 reads (15%) | called by mutect2, pindel, varscan2
- ADAMTSL1 | c.1041C>A p.P347= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as COSV99440407; called by muse, mutect2, varscan2
- ADCY10 | c.2802G>A p.Q934= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV100896482; called by muse, mutect2, varscan2
- ADORA1 | c.201C>A p.I67= | Silent (SNP) | VAF 34/154 reads (22%) | catalogued as COSV100525970; called by muse, mutect2, varscan2
- BAZ1B | c.3010C>T p.L1004= | Silent (SNP) | VAF 27/143 reads (19%) | catalogued as COSV100289464; called by muse, mutect2, varscan2
- CACNA1S | c.522G>A p.R174= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV100754523; called by muse, mutect2, varscan2
- CALD1 | c.480C>T p.Y160= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs113157290; called by muse, varscan2
- CCDC180 | c.447G>A p.A149= | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as rs879199350, COSV63835288; called by muse, mutect2
- CIZ1 | c.2280G>A p.E760= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV99476571; called by muse, mutect2, varscan2
- CNTN1 | c.1308C>T p.C436= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100750781; called by muse, mutect2, varscan2
- CNTNAP3 | c.2448C>T p.D816= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs780612729, COSV52668090; called by muse, mutect2, varscan2
- COL15A1 | c.1398C>T p.T466= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs200379044, COSV100897294; called by muse, mutect2, varscan2
- DCK | c.765G>A p.E255= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV99709067; called by muse, mutect2, varscan2
- DCST1 | c.2076C>T p.S692= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99664612; called by muse, mutect2, varscan2
- EVC2 | c.603G>A p.S201= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs200083464, COSV100184804, COSV60403141; called by muse, mutect2, varscan2
- FAT4 | c.13506G>T p.L4502= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV100626903; called by muse, mutect2
- GNPAT | c.132T>C p.H44= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV100791526; called by muse, mutect2, varscan2
- H3C3 | c.27C>G p.R9= | Silent (SNP) | VAF 39/124 reads (31%) | catalogued as rs752104215, COSV100778226, COSV100778303; called by muse, mutect2, varscan2
- IL27 | c.12G>A p.T4= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs778111614, COSV100795796, COSV63560262; called by muse, mutect2, varscan2
- KRT28 | c.843C>T p.F281= | Silent (SNP) | VAF 16/238 reads (7%) | catalogued as COSV60683661; called by muse, mutect2
- LHFPL6 | c.13C>T p.L5= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV101094910; called by muse, mutect2, varscan2
- LRP1B | c.6210G>A p.E2070= | Silent (SNP) | VAF 32/154 reads (21%) | catalogued as COSV101250042; called by muse, mutect2, varscan2
- MTMR9 | c.1446C>A p.I482= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV99643844; called by muse, mutect2, varscan2
- MXRA5 | c.6339G>A p.A2113= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs770918368, COSV99475388; called by muse, varscan2
- MYO9B | c.2271C>T p.G757= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs754328459; called by mutect2, varscan2
- MYO9B | c.6006G>A p.S2002= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs568384629, COSV99812296; called by muse, mutect2, varscan2
- NTRK1 | c.291C>T p.T97= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs1057522997, COSV100693076; ClinVar: likely benign; called by muse, varscan2
- OR1E2 | c.252C>T p.N84= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV99943342; called by muse, mutect2, varscan2
- OR2T33 | c.531C>T p.C177= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs746857030, COSV58815948; called by muse, mutect2, varscan2
- PATJ | c.1719A>G p.E573= | Silent (SNP) | VAF 37/174 reads (21%) | catalogued as rs904774253, COSV100332836; called by muse, mutect2, varscan2
- POSTN | c.153C>A p.G51= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV101123199; called by muse, mutect2, varscan2
- PPIB | c.402G>A p.G134= | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as COSV100254353; called by muse, mutect2, varscan2
- RANBP6 | c.3171G>A p.E1057= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV99423882; called by muse, mutect2, varscan2
- RPE65 | c.75G>A p.P25= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs199529021, COSV52016426; ClinVar: likely benign; called by mutect2, varscan2
- SLC52A3 | c.660C>T p.P220= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99447490; called by muse, mutect2, varscan2
- SULF2 | c.2094G>A p.L698= | Silent (SNP) | VAF 26/152 reads (17%) | catalogued as COSV100736913; called by muse, mutect2, varscan2
- TSC22D2 | c.2307G>A p.T769= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as rs756957480, COSV62623003; called by muse, mutect2, varscan2
- WDFY3 | c.5580G>A p.E1860= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV99881488; called by muse, mutect2
- ZFHX4 | c.8685C>T p.N2895= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs1050352487, COSV50648141; called by muse, mutect2, varscan2
- C11orf40 | n.187T>G | RNA (SNP) | VAF 24/71 reads (34%) | catalogued as rs1381624612, COSV56890537; called by muse, mutect2, varscan2
- KAT6A | c.1483-1854C>A | Intron (SNP) | VAF 19/90 reads (21%) | called by muse, mutect2, varscan2
- POR | c.-4-10113C>T | Intron (SNP) | VAF 66/150 reads (44%) | catalogued as rs782496982, COSV100792795; called by muse, mutect2, varscan2
